Somatic mutation profile of tumor specimen ALCH-B46M-TTP1-A (aliquot ALCH-B46M-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B46M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.2 years (23,817 days).
Specimen ALCH-B46M-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9c09f5d-1b76-4836-9110-c3374884f74d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B46M-NB1-A (Blood Derived Normal), aliquot ALCH-B46M-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5a56687-8ca1-447d-8d72-1b03da601534

The open-access MAF lists 89 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Intron 5, Nonsense Mutation 4, RNA 2, 5'UTR 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 29/231 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- AKAP9 | c.9307A>G p.M3103V (on ENST00000359028; = p.M3079V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as rs761190206; called by muse, mutect2, varscan2
- BMS1 | c.2481T>G p.D827E | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs754665507; called by muse, mutect2, varscan2
- CNTNAP4 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | catalogued as COSV56690887; called by muse, mutect2, varscan2
- COL5A2 | c.3497C>A p.A1166D | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV66408585; called by muse, mutect2, varscan2
- DNAH5 | c.12076G>A p.E4026K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776854779, COSV54239439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA10 | c.1571G>C p.R524P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV57623705; called by muse, mutect2, varscan2
- ERBB4 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53566237; called by muse, mutect2
- FASTKD3 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as rs1209204066; called by muse, mutect2
- JPH2 | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV65902940; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.32); catalogued as COSV51718592; called by muse, mutect2, varscan2
- MUC2 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); catalogued as COSV61245140; called by muse, mutect2
- MYF5 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1266845323; called by muse, mutect2, varscan2
- MYH6 | c.4192C>T p.R1398W | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs374022661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143332486, COSV67974858; called by muse, mutect2, varscan2
- OCLN | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs759259792, COSV62285438; called by muse, mutect2, varscan2
- OR8H3 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57911253; called by muse, mutect2, varscan2
- PPM1L | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377495364; called by muse, mutect2, varscan2
- SLC9A1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as rs1176707587; called by muse, mutect2, varscan2
- TNR | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54893337; called by muse, mutect2, varscan2
- TTLL7 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53083843; called by muse, mutect2
- ZNF638 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs767809339; called by muse, mutect2, varscan2
- ZNF676 | c.1597G>T p.G533* (on ENST00000650058; = p.G501* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 24/207 reads (12%) | catalogued as COSV68094911; called by muse, mutect2, varscan2
- ABCB4 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.346); called by muse, varscan2
- ALCAM | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AP000721.1 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ATP11B | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- C10orf53 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CATSPERB | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCP110 | c.1810A>G p.I604V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDKN1A | c.4T>G p.S2A | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.079); called by muse, mutect2
- CEP295NL | c.1643C>A p.A548D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- GRM5 | c.3426G>C p.E1142D (on ENST00000305447 / NM_001143831.2; = p.E1110D on NM_000842.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNJ3 | c.1402G>C p.A468P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, varscan2
- KCTD8 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LILRA2 | c.1140C>A p.F380L | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP12 | c.1309A>T p.N437Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MANBA | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MARK3 | c.1942G>C p.D648H (on ENST00000429436 / NM_001128918.3; = p.D624H on NM_002376.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by mutect2, varscan2
- MATN1 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MPP5 | c.1041+2_1041+4del p.X347_splice | Splice Site (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- MYO5B | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NDST3 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6T1 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR8H3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PAK1IP1 | c.190A>T p.I64F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G7 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.238); called by muse, mutect2
- PRKAB2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRKCH | c.1995G>A p.M665I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2
- PSMA5 | c.291+6A>T | Splice Region (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2539T>A p.F847I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- S1PR2 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SEMA3D | c.1547A>C p.Q516P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, varscan2
- SNTG2 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBCCD1 | c.1024A>T p.I342L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TPO | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TPRN | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TPRN | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- VPS37A | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF566 | c.822G>C p.Q274H | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF597 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.129); called by muse, mutect2
- CDC37 | c.732C>T p.A244= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs955251838, COSV55769206; called by muse, mutect2, varscan2
- CR1L | c.510T>A p.T170= | Silent (SNP) | VAF 44/165 reads (27%) | called by muse, varscan2
- FAM219A | c.462C>T p.P154= (on ENST00000445726; = p.P137= on NM_147202.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs368703121; called by muse, mutect2, varscan2
- FLNC | c.1626T>A p.P542= | Silent (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- FMNL2 | c.366C>T p.V122= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- GFRA1 | c.351G>A p.E117= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as COSV100815942; called by muse, mutect2
- GPATCH1 | c.588C>T p.P196= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- GPR152 | c.1305G>A p.S435= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1236423959, COSV56887588; called by muse, mutect2, varscan2
- JRK | c.1290C>T p.G430= | Silent (SNP) | VAF 26/207 reads (13%) | called by muse, mutect2, varscan2
- LCA5 | c.1755A>G p.E585= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- LRP1 | c.8229C>T p.N2743= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- OR5I1 | c.207A>T p.S69= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- PRRC2B | c.2550C>G p.L850= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- RYR3 | c.10518C>T p.L3506= (on ENST00000389232; = p.L3507= on NM_001036.6) | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs754817196; called by muse, mutect2, varscan2
- SDK2 | c.2685T>A p.P895= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- ZNF676 | c.1596T>C p.T532= (on ENST00000650058; = p.T500= on NM_001001411.3) | Silent (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- ZNF91 | c.2559C>G p.L853= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs371611077; called by muse, mutect2, varscan2
- CXorf65 | c.-33G>T | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- HLA-V | n.4195G>T | RNA (SNP) | VAF 18/141 reads (13%) | called by muse, varscan2
- MIR381 | n.11G>T | RNA (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 6/116 reads (5%) | catalogued as rs910081914; called by muse, mutect2
- SMARCA4 | c.3547-36G>A | Intron (SNP) | VAF 14/122 reads (11%) | called by mutect2, varscan2
- SMOX | c.1531-526A>T | Intron (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- SPSB4 | c.695-14871T>G | Intron (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- ST6GALNAC2 | c.126-14G>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- TRAV8-4 | c.-17G>A | 5'UTR (SNP) | VAF 17/115 reads (15%) | catalogued as rs772008309; called by muse, mutect2, varscan2
